Somatic mutation profile of tumor specimen TCGA-BR-8295-01A (aliquot TCGA-BR-8295-01A-11D-2340-08) from TCGA case TCGA-BR-8295, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 60.9 years (22,256 days).
Specimen TCGA-BR-8295-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb89b210-0ecf-4c88-9af7-bf1d3ffde4c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8295-10A (Blood Derived Normal), aliquot TCGA-BR-8295-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/766a1d6c-d14c-498a-8e7f-ee92f963cf36

The open-access MAF lists 58 somatic variants for this specimen: 43 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 14, Frame Shift Del 4, Nonsense Mutation 2, RNA 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DGUOK | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 24/83 reads (29%) | catalogued as rs104893630, CM021575, COSV51205581; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.719_727del p.S240_C242del | In Frame Del (DEL) | VAF 13/34 reads (38%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- CEP128 | c.1918C>G p.L640V | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV55393503; called by muse, mutect2, varscan2
- CFAP161 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.121); catalogued as rs762555812, COSV54430784; called by muse, mutect2, varscan2
- CNTNAP2 | c.265T>G p.F89V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV62148261, COSV62271311; called by muse, mutect2, varscan2
- DMBT1 | c.5075A>G p.Q1692R (on ENST00000338354 / NM_001377530.1; = p.Q935R on NM_004406.3) | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs374308103, COSV100354085; called by muse, varscan2
- DOK6 | c.719A>T p.E240V | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV66938841; called by muse, mutect2, varscan2
- ERBB4 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as rs1229970702, COSV53500900; called by muse, mutect2, varscan2
- F11R | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV57041261; called by muse, mutect2, varscan2
- GALNT17 | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61197769; called by muse, varscan2
- GCN1 | c.6474G>C p.E2158D | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV56116068; called by muse, mutect2, varscan2
- IGHV3-43 | c.206T>G p.L69R | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs1354352889; called by muse, mutect2, varscan2
- KCNH8 | c.1847C>G p.A616G | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV60479962; called by muse, mutect2, varscan2
- KDELR3 | c.366_369del p.F122Lfs*15 | Frame Shift Del (DEL) | VAF 39/200 reads (20%) | catalogued as rs753780926; called by mutect2, pindel, varscan2
- LAMA1 | c.155T>A p.L52H | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67545599; called by muse, mutect2, varscan2
- LHX9 | c.1108A>G p.I370V | Missense Mutation (SNP) | VAF 84/97 reads (87%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV61326615; called by muse, mutect2, varscan2
- LRRC1 | c.734T>A p.L245* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | catalogued as COSV63831171; called by muse, mutect2, varscan2
- LRRK2 | c.3108T>G p.S1036R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.253); catalogued as COSV54174899; called by muse, mutect2, varscan2
- MAGEB1 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.197); catalogued as rs747784071, COSV100975132, COSV66776023; called by muse, mutect2, varscan2
- MCOLN2 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV52299875, COSV52300369; called by muse, mutect2, varscan2
- MIOS | c.617G>C p.R206P | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV60768543, COSV60771125; called by muse, mutect2, varscan2
- NEIL1 | c.336_337del p.C113Ffs*42 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs1435000281; called by mutect2, pindel, varscan2
- NQO2 | c.458C>G p.A153G | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV57643921; called by muse, mutect2, varscan2
- OCLN | c.815A>G p.D272G | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV62286219; called by muse, mutect2, varscan2
- OR5M3 | c.148A>G p.S50G | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV56568839; called by muse, mutect2, varscan2
- PCDHA12 | c.2036C>T p.S679L | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as rs892674985, COSV56552943; called by muse, mutect2, varscan2
- PLBD2 | c.764G>A p.S255N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.158); catalogued as COSV55109367; called by muse, mutect2, varscan2
- POLR3C | c.585G>C p.L195F | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV61937675; called by muse, mutect2, varscan2
- PTPRU | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as rs149813959; called by muse, mutect2, varscan2
- RAD51AP2 | c.110G>A p.C37Y | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as rs779368183, COSV67589477; called by muse, mutect2, varscan2
- RANBP10 | c.1108C>G p.P370A | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as COSV58162224; called by muse, mutect2, varscan2
- RFPL2 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs778375746, COSV50710513; called by muse, mutect2, varscan2
- SPHKAP | c.3087A>T p.E1029D | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.029); catalogued as COSV60898154; called by muse, mutect2, varscan2
- TENT5A | c.270C>A p.F90L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV60789905; called by muse, mutect2, varscan2
- WAS | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs369850591, COSV64997888; called by muse, mutect2, varscan2
- WFIKKN2 | c.1139G>A p.S380N | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV60960419; called by muse, mutect2, varscan2
- ZNF714 | c.1334G>C p.R445T | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV52510805, COSV52516394; called by muse, mutect2, varscan2
- CAV2 | c.199_202del p.D67Kfs*16 | Frame Shift Del (DEL) | VAF 39/79 reads (49%) | called by mutect2, pindel, varscan2
- MUC16 | c.35677_35678del p.L11893Dfs*17 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by pindel, varscan2
- MUC5B | c.7489A>G p.S2497G | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR1C1 | c.862T>G p.F288V | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2
- RPL10 | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SYNCRIP | c.1182dup p.D395Rfs*8 | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- AGTR1 | c.240T>G p.T80= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV62560526; called by muse, mutect2, varscan2
- C12orf66 | c.1188C>G p.T396= | Silent (SNP) | VAF 8/170 reads (5%) | catalogued as COSV61325163; called by muse, mutect2
- CFTR | c.3546C>T p.Y1182= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as CM941985, COSV50122488; called by muse, mutect2, varscan2
- ERLIN2 | c.870T>A p.A290= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV52422303; called by muse, mutect2, varscan2
- LAMC3 | c.456C>T p.R152= | Silent (SNP) | VAF 39/62 reads (63%) | catalogued as rs368974870, COSV63089470, COSV63094410; called by muse, mutect2, varscan2
- MUC5B | c.7488G>T p.V2496= | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- NABP1 | c.126G>C p.V42= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV57139525; called by muse, mutect2, varscan2
- OR4A47 | c.645T>C p.S215= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV71445211; called by muse, mutect2, varscan2
- PHLDB2 | c.498G>A p.G166= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV67316809; called by muse, mutect2, varscan2
- PNMA8B | c.1614G>A p.A538= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV66537972; called by muse, varscan2
- RIMBP2 | c.2484A>G p.R828= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV55486626; called by muse, mutect2, varscan2
- TLR6 | c.1764C>T p.I588= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV67935911; called by muse, mutect2, varscan2
- ZAP70 | c.1182C>T p.D394= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV53858096; called by muse, mutect2, varscan2
- ZBTB38 | c.420A>G p.E140= | Silent (SNP) | VAF 54/92 reads (59%) | catalogued as COSV58544791; called by muse, mutect2, varscan2
- OR2W5 | n.483C>A | RNA (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
